Somatic mutation profile of tumor specimen 0DJKKN from CCDI case PBBWJM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 3.8 years (1,375 days).
Specimen 0DJKKN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d09839c6-51ad-45d7-ab2c-24dca345b406.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJKK6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4586305f-7aee-4e0c-965d-29053efc6482

The open-access MAF lists 46 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Intron 7, Silent 6, 5'UTR 4, 3'UTR 2, 5'Flank 1, Nonsense Mutation 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 472/850 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- AHDC1 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs778905709; called by muse, mutect2, varscan2
- CAND2 | c.1291C>T p.R431C (on ENST00000456430 / NM_001162499.2; = p.R338C on NM_012298.3) | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs993019070; called by muse, mutect2, varscan2
- KCNB2 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 44/1402 reads (3%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.345); catalogued as COSV73049849; called by muse, mutect2
- NOTCH1 | c.1199G>T p.C400F | Missense Mutation (SNP) | VAF 41/435 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV53078862; called by muse, mutect2, varscan2
- PAIP1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.264); catalogued as rs1032703598; called by muse, mutect2
- PIAS4 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs1219553427; called by muse, mutect2, varscan2
- SOAT2 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 154/762 reads (20%) | catalogued as rs761081560; called by muse, mutect2, varscan2
- TRAK1 | c.441C>G p.N147K (on ENST00000327628 / NM_001349247.2; = p.N89K on NM_014965.5) | Missense Mutation (SNP) | VAF 142/796 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs747039605, COSV58256732; called by muse, mutect2, varscan2
- ADGRL3 | c.3009C>A p.D1003E (on ENST00000506720 / NM_001322402.2; = p.D935E on NM_015236.6) | Missense Mutation (SNP) | VAF 82/1113 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.085); called by muse, mutect2
- DMXL1 | c.7784G>T p.W2595L | Missense Mutation (SNP) | VAF 41/1270 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- DNAH14 | c.1622G>A p.R541K (on ENST00000445597; = p.R522K on NM_001367479.1) | Missense Mutation (SNP) | VAF 141/1629 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2
- ENKD1 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- GLI2 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 22/626 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.565); called by muse, mutect2
- MSR1 | c.771A>C p.K257N | Missense Mutation (SNP) | VAF 295/2683 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2T4 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 323/1040 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OR6K6 | c.820G>T p.V274L (on ENST00000368144; = p.V250L on NM_001005184.1) | Missense Mutation (SNP) | VAF 50/974 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- OTP | c.521C>A p.T174K | Missense Mutation (SNP) | VAF 32/716 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2
- POTEJ | c.1948A>C p.N650H | Missense Mutation (SNP) | VAF 223/1939 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SLFN14 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 54/701 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- TEX101 | c.209-2A>G p.X70_splice (on ENST00000598265 / NM_001130011.3; = p.X88_splice on NM_031451.4) | Splice Site (SNP) | VAF 18/404 reads (4%) | called by muse, mutect2
- TFE3 | c.788_790del p.D263del | In Frame Del (DEL) | VAF 54/294 reads (18%) | called by pindel, varscan2
- TFE3 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VEPH1 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 157/774 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZFHX4 | c.2397G>C p.Q799H | Missense Mutation (SNP) | VAF 98/2464 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF799 | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 88/1356 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- BICRA | c.3264G>A p.L1088= | Silent (SNP) | VAF 30/556 reads (5%) | called by muse, mutect2
- DTX3 | c.684A>G p.L228= | Silent (SNP) | VAF 150/658 reads (23%) | called by muse, mutect2, varscan2
- GPAT3 | c.420G>C p.R140= | Silent (SNP) | VAF 82/1064 reads (8%) | called by muse, mutect2
- MGAM2 | c.5994T>A p.P1998= | Silent (SNP) | VAF 88/1818 reads (5%) | called by muse, mutect2
- PTPRO | c.843C>T p.S281= | Silent (SNP) | VAF 272/1339 reads (20%) | catalogued as rs767560556, COSV55510654; called by muse, mutect2, varscan2
- RFX3 | c.1518C>A p.A506= | Silent (SNP) | VAF 278/986 reads (28%) | catalogued as rs138397915; called by mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- GUF1 | c.-26C>G | 5'UTR (SNP) | VAF 139/792 reads (18%) | called by muse, mutect2, varscan2
- IMPDH2 | c.1439+10G>C | Intron (SNP) | VAF 72/1167 reads (6%) | called by muse, mutect2
- MORF4L1 | c.-47G>A | 5'UTR (SNP) | VAF 39/138 reads (28%) | called by mutect2, varscan2
- NRG1 | c.701-4857del | Intron (DEL) | VAF 147/1530 reads (10%) | catalogued as rs1376075072; called by mutect2, pindel, varscan2
- OR5AR1 | c.*31A>T | 3'UTR (SNP) | VAF 42/630 reads (7%) | called by muse, mutect2
- P2RX3 | c.-1C>A | 5'UTR (SNP) | VAF 40/527 reads (8%) | called by muse, mutect2
- PTK2 | c.195+34T>C | Intron (SNP) | VAF 171/1332 reads (13%) | called by muse, mutect2, varscan2
- PTPRO | c.*16+30T>A | Intron (SNP) | VAF 57/514 reads (11%) | called by muse, mutect2, varscan2
- SPATA48 | c.*42G>A | 3'UTR (SNP) | VAF 15/358 reads (4%) | called by muse, mutect2
- TCERG1L | c.-80G>T | 5'UTR (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- TTLL10 | c.1401+109C>T | Intron (SNP) | VAF 23/113 reads (20%) | catalogued as rs912238171, COSV101016321; called by muse, mutect2, varscan2
- WNT16 | chr7:121325405 G>A | 5'Flank (SNP) | VAF 46/710 reads (6%) | catalogued as rs769316286; called by muse, mutect2
- XAB2 | c.200+67G>T | Intron (SNP) | VAF 57/224 reads (25%) | called by muse, mutect2, varscan2
